Gene-level copy-number profile of tumor specimen TCGA-29-1701-01A from TCGA case TCGA-29-1701, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.8 years (20,737 days).
Specimen TCGA-29-1701-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.fe1cab9b-cff2-4467-ba52-134831acf48d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1701-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/60752c5b-760f-4f70-b87e-53b4ed7b20c0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 183; copy number 2: 16,452; copy number 3: 21,788; copy number 4: 13,870; copy number 5: 4,811; copy number 6: 688; copy number 7: 711; copy number 8: 252; copy number 9: 416; copy number 10: 77; copy number 11: 21; copy number 12: 143; copy number 13: 33; copy number 14: 28; copy number 15: 131; copy number 16: 18; copy number 18: 51; copy number 19: 71; copy number 22: 28; copy number 23: 4; copy number 30: 23; copy number 36: 1; copy number 38: 3; copy number 41: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1701-01A-01D-0559-01): tumor purity 0.71, ploidy 3.35, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,023 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:61,145,068–61,191,203, 3 genes, copy number 7: C2orf74, AC016747.2, AHSA2P.
- chr2:61,199,979–61,250,621, 2 genes, copy number 7: AC016747.3, AC018889.1.
- chr2:111,006,015–111,523,376, 1 gene, copy number 8 (within-gene range 2–8): MIR4435-2HG.
- chr2:111,195,963–112,614,431, 42 genes, copy number 8 (within-gene range 6–8): AC108463.2, AC108463.1, AC108463.3, AC068491.1, AC068491.2, RPS14P4, MIR4435-2, PAFAH1B1P2, AC017002.3, AC017002.2, SOCAR, DBF4P2, AC017002.1, ANAPC1, RPL34P8, AC093166.1, CENPNP2, MIR4771-2, AC093166.2, EEF1E1P1, MERTK, RN7SL297P, RTRAFP1, SLC30A6P1, AC093675.1, TMEM87B, AC093675.2, FBLN7, AC092645.1, ZC3H8, AC092645.2, ZC3H6, NDUFB4P6, AC115115.1, RGPD8, VINAC1P, TTL, POLR1B, Y_RNA, CHCHD5, AC012442.2, AC012442.1.
- chr2:113,022,089–114,261,226, 43 genes, copy number 8 (within-gene range 6–8): IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2, AC017074.1, RNU6-744P, SLC35F5, MIR4782, AC104653.2, AC104653.1, AC110769.2, ACTR3, AC110769.3, LINC01191, AC110769.1, U3, AC010982.2, AC010982.1, SEPHS1P7.
- chr2:114,828,432–114,835,588, 2 genes, copy number 19: DPP10-AS3, DPP10-AS2.
- chr2:120,651,273–123,444,445, 27 genes, copy number 9: Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823, AC011246.1, AC073632.1, AC062020.1, LINC01826, AC073409.2, AC073409.1.
- chr2:124,025,287–128,519,177, 69 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr4:56,288,485–59,834,167, 55 genes, copy number 7–12: RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1, SRIP1, AC096725.1, LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P.
- chr4:60,750,575–82,581,384, 350 genes, copy number 8–10 (broad region; genes not listed).
- chr7:84,983,556–89,754,726, 45 genes, copy number 9–14: HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47, AC002383.1, RNU6-274P.
- chr8:41,653,220–41,896,762, 1 gene, copy number 8 (within-gene range 5–8): ANK1.
- chr8:41,803,349–42,051,994, 4 genes, copy number 8 (within-gene range 4–8): Y_RNA, AC027702.1, RN7SL149P, KAT6A.
- chr8:100,133,351–107,195,938, 141 genes, copy number 9–15 (broad region; genes not listed).
- chr8:112,222,928–113,616,958, 8 genes, copy number 7: CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1.
- chr8:126,325,454–137,105,458, 131 genes, copy number 15–41 (broad region; genes not listed).
- chr9:1,977,784–3,053,408, 14 genes, copy number 7: AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1.
- chr9:6,413,151–7,961,224, 26 genes, copy number 8: UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1, KDM4C, PRELID3BP11, SNRPEP2, ACTG1P14, AL513412.1, AL161443.1, AL157703.1, RPL4P5, PPIAP33, AL354694.1, DMAC1, AL135923.2, AL135923.1.
- chr9:8,700,595–9,091,245, 6 genes, copy number 8: AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3.
- chr9:22,203,990–24,545,946, 18 genes, copy number 16: AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3.
- chr9:30,388,935–30,575,012, 1 gene, copy number 11 (within-gene range 6–11): LINC01242.
- chr10:44,712–15,171,278, 277 genes, copy number 7 (broad region; genes not listed).
- chr10:15,237,492–15,241,767, 1 gene, copy number 7: AL607028.1.
- chr10:18,513,115–42,185,791, 361 genes, copy number 7 (broad region; genes not listed).
- chr12:3,381,349–4,405,490, 19 genes, copy number 7 (within-gene range 4–7): PRMT8, AC005908.2, AC005908.1, THCAT155, CRACR2A, AC005831.1, RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1.
- chr12:43,793,723–46,373,778, 33 genes, copy number 11–19 (within-gene range 3–19): TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, AC025253.2, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2.
- chr12:46,384,233–46,652,550, 5 genes, copy number 19 (within-gene range 3–19): AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P.
- chr12:48,350,945–48,442,411, 1 gene, copy number 19 (within-gene range 3–19): AC090115.1.
- chr12:48,394,510–48,628,836, 12 genes, copy number 19: OR5BJ1P, OR8S21P, OR8T1P, ANP32D, C12orf54, AC089987.2, RPS10P20, AC089987.1, OR8S1, OR5BS1P, LALBA, OR11M1P.
- chr12:48,654,382–48,656,782, 3 genes, copy number 19: SNORA2C, MIR1291, SNORA2A.
- chr12:53,985,065–54,896,008, 51 genes, copy number 18 (within-gene range 3–18): HOXC10, AC012531.3, HOXC6, MIR196A2, HOXC-AS2, HOXC9, HOXC-AS1, HOXC8, HOXC4, AC012531.2, AC012531.1, HOXC5, MIR615, FLJ12825, AC023794.3, AC023794.2, FAM242C, Y_RNA, SMUG1, LINC02381, AC023794.5, AC023794.4, AC023794.1, CBX5, MIR3198-2, RN7SL390P, SCAT2, AC078778.1, HNRNPA1, NFE2, COPZ1, RNU6-950P, MIR148B, RN7SL744P, AC079313.2, AC079313.1, GPR84, ZNF385A, ITGA5, LINC01154, GTSF1, NCKAP1L, AC068789.1, PDE1B, PPP1R1A, GLYCAM1, LACRT, DCD, AC079310.1, VDAC1P5, MUCL1.
- chr16:24,919,389–25,261,066, 16 genes, copy number 7 (within-gene range 2–7): ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1, ZKSCAN2-DT.
- chr18:40,245,879–42,115,538, 9 genes, copy number 9–10: AC068688.1, AC079052.1, KC6, NPM1P1, AC011225.1, PIK3C3, AC087683.2, AC087683.1, AC087683.3.
- chr18:42,270,589–42,270,715, 1 gene, copy number 10: RNA5SP454.
- chr19:27,638,483–33,589,688, 130 genes, copy number 9–19 (broad region; genes not listed).
- chr19:38,184,376–40,122,168, 115 genes, copy number 8–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 179. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
